Gene-level copy-number profile of tumor specimen ALCH-B3ES-TTP1-A from ALCHEMIST case ALCH-B3ES, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 51.3 years (18,754 days).
Specimen ALCH-B3ES-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 08adc386-fe11-41fe-bf0c-0c26c670f2cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ES-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/508effb2-dbe1-4863-9b75-a20c9a4987a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 4,833; copy number 2: 51,458; copy number 3: 1,927; copy number 4: 99; copy number 5: 6; copy number 6: 4; copy number 7: 1; copy number 20: 4.

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 2 genes (within-gene range 0–2): AL627309.1, AL627309.3.
- chr1:46,432,129–46,482,493, 1 gene (within-gene range 0–2): FAAHP1.
- chr1:180,912,897–180,951,614, 1 gene (within-gene range 0–2): KIAA1614.
- chr1:180,949,699–180,954,887, 1 gene (within-gene range 0–2): KIAA1614-AS1.
- chr2:176,177,717–176,179,008, 1 gene (within-gene range 0–2): HAGLROS.
- chr4:49,212,251–49,212,624, 1 gene: AC118282.2.
- chr5:100,388,853–100,389,938, 1 gene: AC113385.2.
- chr8:22,042,398–22,048,809, 1 gene: FGF17.
- chr8:33,580,210–33,580,508, 1 gene: RN7SL621P.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr9:125,372,325–125,372,766, 1 gene: AL627223.1.
- chr15:25,203,227–25,220,578, 10 genes (within-gene range 0–1): SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:25,227,109–25,241,827, 9 genes (within-gene range 0–1): SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr16:75,228,181–75,268,053, 2 genes (within-gene range 0–2): BCAR1, AC009078.3.
- chr22:41,301,525–41,446,801, 5 genes: ZC3H7B, TEF, RNU6-495P, AL008582.1, TOB2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr4:1,402,932–1,406,442, 1 gene, copy number 7: NKX1-1.
- chr9:129,803,157–129,811,281, 1 gene, copy number 5: TOR1B.
- chr11:86,649–207,428, 6 genes, copy number 6–20 (within-gene range 2–20): OR4F2P, AC069287.1, CICP23, LINC01001, BET1L, SCGB1C1.
- chr12:14,356,842–14,502,935, 2 genes, copy number 6: RPL30P11, ATF7IP.

Autosomal genes at a single copy (total copy number 1): 4,014. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
